CCDI case PBCPXF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f2e5cb63-31bf-4ec2-9b5c-e62783e48193

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Hemangioma, NOS: ICD-O-3 morphology code: 9120/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,908 days).

Biospecimens (3 samples)
- Sample 0DX8JP: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DX8KI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DXMNK: Tissue type: Tumor; Specimen type: Solid Tissue.
